Somatic mutation profile of tumor specimen TCGA-AX-A2HG-01A (aliquot TCGA-AX-A2HG-01A-11D-A17D-09) from TCGA case TCGA-AX-A2HG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 56.9 years (20,771 days).
Specimen TCGA-AX-A2HG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79b08a80-f536-4edf-83e7-4d2cb86ef319.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A2HG-10A (Blood Derived Normal), aliquot TCGA-AX-A2HG-10A-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0e2c454-2a7e-4bd6-8832-3818fdf5b9e7

The open-access MAF lists 996 somatic variants for this specimen: 769 protein-altering or splice-affecting, 209 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 497, Silent 209, Frame Shift Del 186, Frame Shift Ins 28, Nonsense Mutation 22, Splice Site 16, Splice Region 14, Intron 8, RNA 5, In Frame Del 3, Nonstop Mutation 2, 5'Flank 2.

Variants (750 of 996; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ATP2A1 | c.2464del p.R822Gfs*49 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | catalogued as rs751365374, COSV62870629; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BAP1 | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as rs916069743, COSV56237149; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1531G>A p.V511I (on ENST00000288602 / NM_001374244.1; = p.V471I on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as rs121913376, CM123146, COSV56171549, COSV56229839; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRIP1 | c.2947del p.I983Lfs*2 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs774684620; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CCDC40 | c.855+1G>A p.X285_splice | Splice Site (SNP) | VAF 26/62 reads (42%) | catalogued as rs1346603171, COSV99481156; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FERMT1 | c.676del p.Q226Sfs*26 | Frame Shift Del (DEL) | VAF 54/154 reads (35%) | catalogued as rs748240859, COSV54090339; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FLNB | c.6616G>T p.G2206* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as rs886043158, COSV99912246; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FRMD7 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as rs137852208, CM065187, COSV100048767; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HPSE2 | c.57dup p.A20Rfs*45 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | catalogued as rs778121647; ClinVar: pathogenic; called by mutect2, varscan2
- HRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 49/98 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: pathogenic / not provided; called by muse, mutect2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- MUTYH | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769237459, CM053996, COSV58343540; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TBCK | c.1370del p.N457Tfs*15 (on ENST00000273980 / NM_001163436.4; = p.N394Tfs*15 on NM_033115.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as rs746860249, CD164312; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA1 | c.5241G>A p.W1747* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as COSV101036679; called by muse, mutect2, varscan2
- ABCA10 | c.4117G>A p.E1373K | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as rs201375015, COSV52219205, COSV52227710; called by muse, mutect2, varscan2
- ABCC1 | c.2600G>A p.R867H | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.509); catalogued as rs778539912, COSV100578932; called by muse, mutect2, varscan2
- ABCC3 | c.1187T>C p.I396T | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99558869; called by muse, mutect2, varscan2
- ABCC8 | c.3965C>T p.A1322V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.045); catalogued as COSV100216833; called by muse, mutect2, varscan2
- ABCC9 | c.3413C>T p.A1138V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV99684959; called by muse, mutect2, varscan2
- ACCS | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99772725; called by muse, mutect2, varscan2
- ACTRT2 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs774532554, COSV101007532; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ADAM19 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1332076059, COSV99976509; called by muse, mutect2, varscan2
- ADAM21 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs745476090; called by muse, mutect2, varscan2
- ADAMTS13 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1255730642, COSV100747002; called by muse, mutect2, varscan2
- ADAMTS17 | c.2603G>A p.G868D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99170426, COSV99171179; called by muse, mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS6 | c.815A>G p.E272G | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101124841; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3044C>T p.A1015V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV65889192; called by muse, mutect2, varscan2
- ADGRF4 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs752458241, COSV99348130; called by muse, varscan2
- ADGRG1 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV65636687; called by muse, mutect2, varscan2
- ADGRL1 | c.2959C>T p.R987C (on ENST00000340736 / NM_001008701.3; = p.R982C on NM_014921.5) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1329892867, COSV100529345; called by muse, mutect2, varscan2
- ADORA2A | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100417885; called by muse, mutect2, varscan2
- AFF3 | c.3421G>A p.A1141T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs368703010, COSV57857517; called by muse, mutect2
- AGGF1 | c.774G>T p.L258F | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100461625; called by muse, mutect2
- AGMO | c.995C>A p.S332Y | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV100693821; called by muse, mutect2, varscan2
- AKAP17A | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as rs1345987709, COSV58309680; called by muse, mutect2, varscan2
- ALDH2 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.217); catalogued as COSV99922782; called by muse, mutect2, varscan2
- ALK | c.3026A>C p.D1009A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as COSV101201534; called by muse, varscan2
- ALPK2 | c.590G>T p.R197M | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV100864195; called by muse, mutect2, varscan2
- ALS2CL | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs139526721, COSV100014848; called by muse, mutect2, varscan2
- AMER1 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747418392, COSV57660268, COSV57669249; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | catalogued as rs34047276; called by mutect2, varscan2
- ANKRD44 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV99984416; called by muse, mutect2, varscan2
- ANO7 | c.1472G>T p.R491M (on ENST00000274979; = p.R437M on NM_001370694.2) | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV99237772; called by muse, mutect2, varscan2
- AOC1 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs368886790; called by muse, mutect2, varscan2
- AP1G2 | c.1244C>T p.T415I | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV99846107; called by muse, mutect2, varscan2
- AP2B1 | c.1564C>T p.R522W | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51999922; called by muse, mutect2, varscan2
- AP4B1 | c.2069G>A p.G690D | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as COSV99870645, COSV99871081; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 14/116 reads (12%) | catalogued as rs749401724; called by mutect2, varscan2
- AQP8 | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as COSV99563768; called by muse, mutect2
- ARFGEF1 | c.5401T>C p.S1801P | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV99138134; called by muse, mutect2
- ARFIP1 | c.882G>T p.Q294H (on ENST00000353617 / NM_001287432.1; = p.Q262H on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100617057; called by muse, mutect2, varscan2
- ARHGEF10 | c.2069G>A p.S690N (on ENST00000398564; = p.S665N on NM_014629.4) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as COSV100034143; called by muse, mutect2, varscan2
- ARHGEF28 | c.966T>C p.R322= | Splice Region (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99708443; called by muse, mutect2, varscan2
- ARID2 | c.448A>G p.M150V | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as rs1365406322, COSV100535672; called by muse, mutect2, varscan2
- ARMC5 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1048994571, COSV51658463; called by muse, mutect2
- ASB2 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.79); catalogued as COSV60110262; called by muse, mutect2, varscan2
- ASF1B | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs142438175; called by muse, mutect2, varscan2
- ASF1B | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs932919750, COSV54617127; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 35/109 reads (32%) | catalogued as rs761154268; called by mutect2, varscan2
- ASNSD1 | c.869T>C p.L290P | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99641063; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP1A4 | c.88dup p.M30Nfs*22 | Frame Shift Ins (INS) | VAF 14/34 reads (41%) | catalogued as rs769261788; called by mutect2, varscan2
- ATP2A1 | c.1780G>A p.V594M | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs142091964, COSV62869436; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP5MC2 | c.166A>G p.S56G | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV100100959; called by muse, mutect2, varscan2
- ATP9A | c.869G>T p.R290L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV100124509, COSV58762928; called by muse, mutect2, varscan2
- AVPR1B | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV100899337; called by muse, mutect2, varscan2
- B3GAT1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV100437767; called by muse, mutect2, varscan2
- BAHCC1 | c.3614C>T p.A1205V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.106); catalogued as rs1376121267, COSV100311307; called by muse, mutect2
- BAP1 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1440748203, COSV56233633, COSV99963592; called by muse, mutect2
- BAP1 | c.1489T>C p.S497P | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99963594; called by muse, mutect2, varscan2
- BCL3 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.523); catalogued as rs1481704544, COSV51234236; called by muse, mutect2, varscan2
- BCOR | c.4750A>C p.N1584H (on ENST00000378444 / NM_001123385.2; = p.N1550H on NM_017745.6) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.429); catalogued as COSV100653038; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BCR | c.668T>A p.V223E | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV100006136; called by muse, mutect2, varscan2
- BEND5 | c.1052del p.K351Rfs*15 | Frame Shift Del (DEL) | VAF 34/73 reads (47%) | catalogued as rs756345162, COSV65718189; called by mutect2, varscan2
- BEST2 | c.1116_1118del p.E372del | In Frame Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs1004832185; called by pindel, varscan2
- BICDL1 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as COSV99985771; called by muse, mutect2, varscan2
- BICRA | c.2935del p.A979Pfs*67 | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | catalogued as rs756990560, COSV67605323; called by mutect2, pindel, varscan2
- BPTF | c.6855C>T p.H2285= | Splice Region (SNP) | VAF 19/72 reads (26%) | catalogued as rs782750355, COSV100074387; called by muse, mutect2, varscan2
- BRAP | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59537271; called by muse, mutect2, varscan2
- BTN2A2 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV100760290; called by muse, mutect2, varscan2
- BZW2 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs1274145599, COSV51756666; called by muse, mutect2, varscan2
- C14orf28 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); catalogued as rs1249975930, COSV100290096; called by muse, mutect2, varscan2
- C8B | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs781743688, COSV100980723; called by muse, mutect2, varscan2
- C9orf131 | c.326A>G p.E109G | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV100397979; called by muse, mutect2, varscan2
- CACNA1A | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 5/136 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV100801608; called by muse, mutect2
- CACNA1E | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62430832; called by muse, mutect2, varscan2
- CACNA1G | c.3362G>A p.R1121Q | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs370349028; called by muse, mutect2, varscan2
- CADM3 | c.104C>T p.T35I (on ENST00000368125 / NM_001127173.3; = p.T69I on NM_021189.5) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779373321, COSV100930288; called by muse, mutect2, varscan2
- CAMK2B | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99322848; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 24/57 reads (42%) | catalogued as rs745547658; called by mutect2, varscan2
- CAPN10 | c.290A>G p.Q97R | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99550043; called by muse, mutect2, varscan2
- CAPN2 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs369599821; called by muse, mutect2, varscan2
- CARD11 | c.974A>G p.N325S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV101210596; called by muse, mutect2
- CARD8 | c.832C>A p.L278M (on ENST00000651546 / NM_001184900.3; = p.L228M on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100751036; called by muse, mutect2, varscan2
- CARD9 | c.1181A>T p.E394V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100261048; called by muse, mutect2
- CASKIN1 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as rs777541526, COSV100623881; called by mutect2, varscan2
- CCDC141 | c.2671C>T p.R891W | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs372879210; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC173 | c.1109dup p.N370Kfs*19 | Frame Shift Ins (INS) | VAF 16/62 reads (26%) | catalogued as rs1425656393; called by mutect2, varscan2
- CCDC7 | c.796+1G>A p.X266_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | catalogued as rs150437631; called by muse, mutect2, varscan2
- CCDC71 | c.1245G>T p.W415C | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100422313, COSV100422494; called by muse, mutect2, varscan2
- CCHCR1 | c.1428C>T p.G476= | Splice Region (SNP) | VAF 28/65 reads (43%) | catalogued as COSV100885592; called by muse, mutect2, varscan2
- CCKBR | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 4/51 reads (8%) | catalogued as COSV58099073; called by muse, mutect2
- CCND1 | c.857C>G p.T286R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57119829, COSV99919330; called by mutect2, varscan2
- CCNY | c.551T>C p.L184P | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99590377; called by muse, mutect2, varscan2
- CD2BP2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs779558284, COSV59769236; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDH2 | c.2054C>T p.S685L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1371255423, COSV99296158; called by muse, mutect2, varscan2
- CDH8 | c.1790G>A p.C597Y | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100180209; called by muse, mutect2
- CDK12 | c.2768G>T p.G923V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71002626; called by muse, mutect2
- CDK4 | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99225908; called by muse, mutect2, varscan2
- CDKN2AIP | c.812del p.K271Rfs*31 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as COSV100187779; called by mutect2, pindel, varscan2
- CEACAM16 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1453827347, COSV101312660; called by muse, mutect2, varscan2
- CEP104 | c.2675C>T p.A892V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100986580; called by muse, mutect2, varscan2
- CEP104 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs143501631; called by muse, mutect2, varscan2
- CEP350 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs372724544; called by muse, mutect2, varscan2
- CEP350 | c.5231G>A p.R1744H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760459972, COSV100854400; called by muse, mutect2, varscan2
- CEP350 | c.5275C>T p.R1759C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs768460326, COSV100854401; called by muse, mutect2, varscan2
- CES3 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV100309848; called by muse, mutect2, varscan2
- CHD6 | c.7101C>A p.D2367E | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV100950727; called by muse, mutect2, varscan2
- CHKA | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99694070, COSV99694128; called by muse, mutect2, varscan2
- CHRDL2 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99733627, COSV99733811; called by muse, mutect2, varscan2
- CHRDL2 | c.100C>A p.L34I | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.243); catalogued as COSV99733631; called by muse, varscan2
- CHRNA2 | c.1015G>A p.V339I | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1064797343, COSV53560103; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNE | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.09); catalogued as COSV99544671; called by muse, mutect2, varscan2
- CHST4 | c.19del p.M7* | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs745406065; called by mutect2, pindel, varscan2
- CIPC | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | catalogued as COSV100694431, COSV62377230; called by muse, mutect2
- CLCA1 | c.1423C>A p.L475I | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.931); catalogued as COSV99322038; called by muse, mutect2
- CLCN1 | c.1429A>G p.M477V | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100577818; called by muse, mutect2, varscan2
- CLCN6 | c.2006G>A p.G669D | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV100411687; called by muse, mutect2, varscan2
- CLEC1A | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100191222, COSV100191244; called by muse, mutect2, varscan2
- CLU | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100324177; called by muse, mutect2, varscan2
- CLUH | c.2863G>A p.A955T (on ENST00000435359; = p.A994T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs375997366; called by muse, mutect2, varscan2
- CLUH | c.1324dup p.D442Gfs*99 (on ENST00000435359; = p.D480Gfs*99 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/60 reads (27%) | catalogued as rs752224729; called by mutect2, varscan2
- CMTM3 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV100411747; called by muse, mutect2, varscan2
- CMYA5 | c.11060A>G p.H3687R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV101483944; called by muse, mutect2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | catalogued as rs374805044; called by mutect2, varscan2
- COL11A1 | c.2284del p.R762Gfs*3 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as COSV62175625; called by mutect2, pindel, varscan2
- COL26A1 | c.648del p.S218Lfs*131 (on ENST00000313669 / NM_001278563.3; = p.S216Lfs*131 on NM_133457.4) | Frame Shift Del (DEL) | VAF 47/123 reads (38%) | catalogued as rs762324149; called by mutect2, pindel, varscan2
- COL2A1 | c.3803G>A p.S1268N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100475849; called by muse, mutect2, varscan2
- COPS7A | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs146292223, COSV57527174; called by muse, mutect2, varscan2
- CORO1B | c.426del p.T143Rfs*100 | Frame Shift Del (DEL) | VAF 30/93 reads (32%) | catalogued as rs1168128968; called by pindel, varscan2
- CPNE8 | c.1683G>C p.Q561H | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs746197065, COSV100504096; called by muse, mutect2, varscan2
- CPSF1 | c.491T>C p.F164S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100574288; called by muse, mutect2, varscan2
- CPXM2 | c.1480-1G>T p.X494_splice | Splice Site (SNP) | VAF 5/46 reads (11%) | catalogued as COSV53872210, COSV99581386; called by muse, mutect2, varscan2
- CRB2 | c.3398T>C p.V1133A | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100749564; called by muse, mutect2, varscan2
- CRYBG3 | c.8431A>G p.R2811G | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV99476744; called by muse, mutect2, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CST1 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 34/107 reads (32%) | catalogued as rs756924682; called by mutect2, varscan2
- CSTF3 | c.613del p.M205* | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | catalogued as rs1300471016; called by mutect2, pindel, varscan2
- CTAG2 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as rs1231014434, COSV99055895, COSV99908841, COSV99909137; called by muse, mutect2, varscan2
- CUBN | c.6451del p.D2151Ifs*5 | Frame Shift Del (DEL) | VAF 34/104 reads (33%) | catalogued as rs1564427104, COSV100913681; called by mutect2, pindel, varscan2
- CUX1 | c.724-1G>T p.X242_splice (on ENST00000292535 / NM_181552.4; = p.X253_splice on NM_001913.5) | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99470851; called by muse, mutect2, varscan2
- CYLC1 | c.18G>A p.L6= | Splice Region (SNP) | VAF 20/156 reads (13%) | catalogued as COSV100254277; called by muse, mutect2, varscan2
- CYP2C18 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as rs1478268071, COSV53671954; called by muse, mutect2, varscan2
- CYP2F1 | c.8G>T p.S3I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.059); catalogued as COSV100462595; called by muse, mutect2, varscan2
- DBF4 | c.1223A>G p.K408R | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV55995988, COSV99719201; called by muse, mutect2, varscan2
- DCBLD2 | c.1325T>C p.M442T | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV100471714; called by muse, mutect2, varscan2
- DDB1 | c.3326T>C p.V1109A | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV100074398; called by muse, mutect2, varscan2
- DDX27 | c.624dup p.E209* | Frame Shift Ins (INS) | VAF 19/63 reads (30%) | catalogued as rs1161203803; called by mutect2, pindel, varscan2
- DDX39B | c.736-3del | Splice Region (DEL) | VAF 5/31 reads (16%) | catalogued as rs755280697; called by mutect2, pindel
- DENND4B | c.22del p.R8Gfs*8 | Frame Shift Del (DEL) | VAF 23/51 reads (45%) | catalogued as rs755611865; called by mutect2, varscan2
- DGKE | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as COSV99400775; called by muse, mutect2, varscan2
- DGKH | c.2252C>T p.A751V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as COSV54930517, COSV54939089; called by muse, mutect2, varscan2
- DHCR24 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs369624032; called by muse, mutect2, varscan2
- DHX16 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as rs781736063, COSV64562968; called by muse, mutect2, varscan2
- DIAPH1 | c.2108del p.P703Hfs*65 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs771360300; called by mutect2, varscan2
- DIO1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762243504, COSV100498952, COSV59517926; called by muse, mutect2, varscan2
- DIO2 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.264); catalogued as COSV101375831; called by muse, mutect2, varscan2
- DISP2 | c.3101T>C p.V1034A | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV99139791; called by muse, mutect2
- DMXL2 | c.8756del p.G2919Vfs*48 | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | catalogued as COSV51847581; called by mutect2, pindel, varscan2
- DMXL2 | c.5393G>A p.R1798H | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99196094; called by muse, mutect2, varscan2
- DMXL2 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as rs746881175, COSV51841117; called by muse, mutect2, varscan2
- DNAH2 | c.12763C>T p.R4255W | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1317606600, COSV66727920; called by muse, mutect2, varscan2
- DNMT3B | c.1509C>A p.C503* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99140633; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK6 | c.5980C>T p.P1994S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs867795824, COSV99625046; called by muse, mutect2, varscan2
- DOCK8 | c.3339del p.F1113Lfs*2 | Frame Shift Del (DEL) | VAF 15/107 reads (14%) | catalogued as rs748134881; called by mutect2, varscan2
- DPAGT1 | c.698del p.F233Sfs*28 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | catalogued as rs35482889; called by mutect2, varscan2
- DPYSL3 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs1369407412, COSV100574965; called by muse, mutect2, varscan2
- DRC1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs759868480, COSV99985144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSCAM | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.077); catalogued as COSV101259500; called by muse, mutect2, varscan2
- DSEL | c.2788C>T p.R930* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV59494555, COSV59494633; called by muse, mutect2, varscan2
- DUSP9 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100720085; called by muse, mutect2, varscan2
- E2F1 | c.370del p.E124Rfs*9 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as COSV100593902; called by pindel, varscan2
- EHMT2 | c.2419C>T p.R807W | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs770418733, COSV100977145; called by muse, mutect2, varscan2
- EIF2S1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV99371632; called by muse, mutect2, varscan2
- EIPR1 | c.739T>C p.C247R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101181790; called by muse, mutect2, varscan2
- ELF5 | c.200G>A p.R67H (on ENST00000312319 / NM_198381.2; = p.R57H on NM_001422.4) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs376593969; called by muse, mutect2, varscan2
- ELK3 | c.525dup p.V176Rfs*14 | Frame Shift Ins (INS) | VAF 9/34 reads (26%) | catalogued as rs769175197; called by mutect2, varscan2
- EP300 | c.6553C>T p.R2185* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99607804; called by muse, mutect2, varscan2
- EPHB4 | c.2398G>A p.A800T | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs761850149, COSV62267872; called by muse, mutect2, varscan2
- EPS15 | c.2597A>T p.E866V | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100869447; called by muse, mutect2
- EPS8L1 | c.1087C>G p.P363A (on ENST00000201647 / NM_133180.3; = p.P236A on NM_017729.3) | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99135813; called by muse, mutect2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 19/34 reads (56%) | catalogued as rs768793415; called by mutect2, varscan2
- ERN1 | c.2668A>G p.R890G | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101458406; called by muse, mutect2, varscan2
- ESPNL | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1397304358, COSV100547619; called by muse, mutect2, varscan2
- EVC | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756208272, COSV53838730, COSV99381347; called by muse, mutect2, varscan2
- EXOC3 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as rs764599617, COSV100155200; called by muse, mutect2, varscan2
- EXTL3 | c.2557T>C p.S853P | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99593764, COSV99593829; called by muse, mutect2, varscan2
- EYA1 | c.1441C>A p.L481M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.926); catalogued as COSV100378911, COSV58168989; called by muse, mutect2, varscan2
- FAM102A | c.700A>G p.S234G (on ENST00000373095 / NM_001035254.3; = p.S92G on NM_203305.2) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100305436; called by muse, mutect2, varscan2
- FAM131A | c.768dup p.S257Qfs*60 (on ENST00000310585; = p.S288Qfs*60 on NM_144635.5) | Frame Shift Ins (INS) | VAF 22/81 reads (27%) | catalogued as rs1560244745; called by mutect2, pindel, varscan2
- FAM47C | c.1397C>A p.P466H | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100792384; called by muse, mutect2
- FANCB | c.8G>T p.S3I | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs751501999, COSV100146453; called by muse, mutect2, varscan2
- FANCD2 | c.1954G>A p.V652I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as rs1381447946, COSV99810716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCM | c.2591A>G p.D864G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99950687; called by muse, mutect2
- FBN2 | c.6757+2C>T p.X2253_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as rs770676086, COSV99325814; called by muse, mutect2, varscan2
- FBN2 | c.4784C>T p.T1595I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.059); catalogued as COSV99325820; called by muse, mutect2
- FBXL7 | c.763A>G p.S255G | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV100309341; called by muse, mutect2, varscan2
- FBXO31 | c.996G>A p.T332= | Splice Region (SNP) | VAF 71/196 reads (36%) | catalogued as rs371036788; called by muse, mutect2, varscan2
- FDX2 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs370918608; called by muse, mutect2, varscan2
- FEM1B | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60988353, COSV60988560; called by muse, mutect2, varscan2
- FGD3 | c.367del p.Q123Rfs*51 | Frame Shift Del (DEL) | VAF 41/141 reads (29%) | catalogued as rs777351004, COSV100490512; called by mutect2, pindel, varscan2
- FLG | c.4940C>T p.A1647V | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as rs1401038989, COSV100911170; called by muse, mutect2, varscan2
- FLII | c.2756G>A p.R919Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs867564560, COSV57500996; called by mutect2, varscan2
- FLNA | c.4954G>A p.G1652R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100774412; called by muse, mutect2, varscan2
- FLNA | c.4038G>T p.Q1346H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100774413; called by muse, mutect2, varscan2
- FMO2 | c.440G>A p.S147N | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.073); catalogued as COSV99269004; called by muse, mutect2, varscan2
- FN1 | c.3585G>T p.W1195C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100116536; called by muse, mutect2, varscan2
- FNDC1 | c.726A>T p.Q242H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99795231; called by muse, mutect2, varscan2
- FOXD4 | c.898G>T p.V300F | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as COSV100070714; called by muse, mutect2, varscan2
- FOXL1 | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100206141; called by muse, mutect2, varscan2
- FRMPD1 | c.310A>G p.N104D | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100733506; called by muse, mutect2, varscan2
- FRRS1L | c.693G>T p.W231C | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV101643899; called by muse, mutect2
- FUT3 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as rs373456531; called by muse, mutect2, varscan2
- FYB2 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs566036317, COSV100599356; called by muse, mutect2, varscan2
- GALNT17 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV61148446; called by muse, mutect2, varscan2
- GAS8 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs145845004; called by muse, mutect2, varscan2
- GBA2 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.172); catalogued as rs1272423277, COSV100803328; called by muse, mutect2, varscan2
- GBP1 | c.1665+1G>A p.X555_splice | Splice Site (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100976236; called by muse, mutect2, varscan2
- GGTLC1 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV99600479; called by muse, mutect2, varscan2
- GJD2 | c.7del p.E3Nfs*9 | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | catalogued as COSV99290994; called by mutect2, pindel, varscan2
- GK2 | c.1284G>A p.M428I | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV100725880; called by muse, mutect2, varscan2
- GLG1 | c.3265+1G>A p.X1089_splice | Splice Site (SNP) | VAF 35/99 reads (35%) | catalogued as COSV99215474; called by muse, mutect2, varscan2
- GLRX3 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100487872; called by muse, mutect2, varscan2
- GNB1 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101060767; called by muse, mutect2, varscan2
- GPA33 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs775151573, COSV63300554; called by muse, mutect2, varscan2
- GPR39 | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100257386, COSV61422488; called by muse, mutect2, varscan2
- GPR42 | c.930G>T p.K310N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV101497376; called by muse, mutect2
- GPR50 | c.1849G>A p.V617M | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.028); catalogued as rs750977314, COSV99505820; called by muse, mutect2, varscan2
- GPR52 | c.58A>G p.N20D | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV99268734; called by muse, mutect2, varscan2
- GPRC5B | c.921C>A p.Y307* | Nonsense Mutation (SNP) | VAF 39/95 reads (41%) | catalogued as COSV100314984; called by muse, mutect2, varscan2
- GPRC5B | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV100314986, COSV56028753; called by muse, mutect2, varscan2
- GRHL2 | c.216+2T>C p.X72_splice | Splice Site (SNP) | VAF 20/40 reads (50%) | catalogued as COSV99306351; called by muse, mutect2, varscan2
- GRIK4 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs143215135; called by muse, mutect2, varscan2
- GRIN2D | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.545); catalogued as COSV99616063; called by muse, mutect2, varscan2
- GRM8 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs760631675, COSV58874971; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 44/126 reads (35%) | catalogued as rs754199513; called by mutect2, varscan2
- GUF1 | c.129G>C p.W43C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.109); catalogued as COSV99877136; called by muse, mutect2
- GYS2 | c.546G>A p.W182* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99679566; called by muse, mutect2, varscan2
- H2AB1 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100371533; called by mutect2, varscan2
- H2AX | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.944); catalogued as rs752137831, COSV99597856; called by muse, mutect2, varscan2
- H3C13 | c.179A>C p.E60A | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.15); catalogued as COSV100516053; called by muse, mutect2
- HAPLN3 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs772342574, COSV62084471; called by muse, mutect2, varscan2
- HAS2 | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.75); PolyPhen benign (0.322); catalogued as COSV58266765; called by muse, mutect2, varscan2
- HECTD1 | c.2873+2T>G p.X958_splice | Splice Site (SNP) | VAF 10/26 reads (38%) | catalogued as COSV101125708; called by muse, mutect2, varscan2
- HECTD3 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs766504102, COSV99870002; called by muse, varscan2
- HECW2 | c.2776A>G p.I926V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV99646308; called by muse, mutect2, varscan2
- HGFAC | c.1362del p.R455Gfs*19 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs761929917; called by mutect2, pindel, varscan2
- HIP1 | c.176A>T p.H59L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417174; called by muse, mutect2, varscan2
- HMGB2 | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs772843489, COSV99632648; called by muse, mutect2, varscan2
- HNRNPL | c.1310C>T p.T437I | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs370003343; called by muse, mutect2, varscan2
- HPGD | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99640223; called by muse, mutect2, varscan2
- HR | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.174); catalogued as rs751517320, COSV100455708; called by muse, mutect2, varscan2
- HS6ST3 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100940149; called by muse, mutect2, varscan2
- HTT | c.6004C>T p.R2002C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs759121416, COSV100750558; called by muse, varscan2
- HYAL3 | c.1052G>T p.R351M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.771); catalogued as COSV100269348; called by muse, mutect2, varscan2
- HYKK | c.1067T>G p.V356G | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101195018; called by muse, mutect2, varscan2
- IGF2BP1 | c.941+1G>A p.X314_splice | Splice Site (SNP) | VAF 47/107 reads (44%) | catalogued as rs751435920, COSV99288399; called by muse, mutect2, varscan2
- IGHV2-70 | c.317T>C p.M106T | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs781447645; called by muse, mutect2
- IGSF1 | c.3465G>A p.W1155* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100811950; called by muse, mutect2, varscan2
- IGSF10 | c.5952C>A p.D1984E | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV99177151; called by muse, mutect2, varscan2
- IGSF9B | c.3833T>C p.L1278P | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100317210; called by muse, mutect2
- IGSF9B | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1323017579, COSV58074975; called by muse, mutect2, varscan2
- INAVA | c.173C>G p.S58C | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV100949913; called by muse, mutect2, varscan2
- INPP4A | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV50785873; called by muse, mutect2, varscan2
- INSRR | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV100947172; called by muse, mutect2, varscan2
- INTS5 | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100399525; called by muse, mutect2, varscan2
- INVS | c.1604A>G p.E535G | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99317245; called by muse, mutect2, varscan2
- IPO11 | c.2419del p.S807Lfs*22 | Frame Shift Del (DEL) | VAF 38/87 reads (44%) | catalogued as rs1561359523; called by mutect2, varscan2
- IQGAP1 | c.4749T>G p.N1583K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as COSV99184898; called by muse, mutect2, varscan2
- IRF8 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs755555074, COSV99236200; called by muse, mutect2, varscan2
- ISLR2 | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs748690445, COSV100679452, COSV62302498; called by muse, mutect2, varscan2
- ITM2B | c.93del p.D32Tfs*30 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as rs746700992; called by mutect2, varscan2
- ITPR3 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs760333138, COSV65409275; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 40/95 reads (42%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- JAM3 | c.745del p.V249Ffs*10 | Frame Shift Del (DEL) | VAF 32/113 reads (28%) | catalogued as rs763250381; called by mutect2, pindel, varscan2
- JMJD8 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.306); catalogued as COSV99555491; called by muse, mutect2
- KANSL1 | c.611del p.G204Vfs*2 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs1304078301; called by mutect2, pindel, varscan2
- KCNA3 | c.1663A>G p.T555A | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV100871222, COSV100871305; called by muse, mutect2, varscan2
- KCNA5 | c.1510G>A p.G504R | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229050065, COSV52904629, COSV52908015; called by muse, mutect2
- KCNC2 | c.1486C>A p.H496N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.15); catalogued as COSV100128437; called by muse, mutect2, varscan2
- KCND1 | c.1733A>G p.N578S | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1557057362, COSV99501803; called by muse, mutect2, varscan2
- KCNJ12 | c.703C>G p.P235A | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as rs782490933, COSV100054272; called by mutect2, varscan2
- KCNJ3 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54535418; called by muse, mutect2, varscan2
- KCNQ4 | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.554); catalogued as COSV61272692; called by muse, mutect2, varscan2
- KCNS2 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1480950741, COSV99750882; called by muse, mutect2, varscan2
- KCTD3 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV52072176; called by muse, mutect2, varscan2
- KCTD8 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100759328; called by muse, mutect2, varscan2
- KDM3A | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57225786; called by muse, mutect2, varscan2
- KHSRP | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs765261230, COSV101231160; called by muse, mutect2, varscan2
- KIAA0100 | c.4780G>T p.G1594C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101197246; called by muse, mutect2
- KIAA1614 | c.1097C>A p.P366H | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV100851165; called by muse, mutect2, varscan2
- KIF1A | c.2041A>G p.R681G | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV100240187; called by muse, mutect2, varscan2
- KIF26B | c.6272G>A p.C2091Y | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374042654; called by muse, mutect2, varscan2
- KIF2C | c.1874A>G p.E625G | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs746788941, COSV100945641; called by muse, mutect2, varscan2
- KIFC1 | c.1576G>A p.V526M | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100996016; called by muse, mutect2, varscan2
- KIFC3 | c.1867A>G p.N623D | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV101109123; called by muse, mutect2, varscan2
- KLHL23 | c.1298A>G p.Y433C | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs758216856, COSV99775609; called by muse, mutect2, varscan2
- KMT2E | c.5511T>G p.I1837M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); catalogued as COSV99995979; called by muse, mutect2, varscan2
- KRT6A | c.1550A>G p.Y517C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV58108014; called by muse, mutect2, varscan2
- KSR1 | c.872dup p.P292Tfs*22 (on ENST00000644974 / NM_001367810.1; = p.P155Tfs*22 on NM_014238.2) | Frame Shift Ins (INS) | VAF 14/39 reads (36%) | catalogued as rs750491454; called by mutect2, varscan2
- LCN12 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV100861307; called by muse, mutect2, varscan2
- LEFTY1 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs751385730, COSV55282294, COSV55283555; called by muse, mutect2, varscan2
- LGALS8 | c.631G>A p.A211T (on ENST00000341872; = p.A253T on NM_006499.4) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV99436324; called by muse, mutect2, varscan2
- LGALS9C | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV100055526; called by muse, varscan2
- LGALS9C | c.540del p.K180Nfs*38 | Frame Shift Del (DEL) | VAF 31/160 reads (19%) | catalogued as rs1405737302; called by pindel, varscan2
- LIFR | c.2554G>A p.V852M | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs752083301, COSV99663616; called by muse, mutect2, varscan2
- LIG3 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99252327; called by muse, mutect2
- LIMS2 | c.634G>A p.A212T (on ENST00000355119 / NM_001161403.3; = p.A236T on NM_017980.4) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs762554883, COSV55755307; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMF1 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.607); catalogued as rs778646907, COSV51900835; called by muse, mutect2, varscan2
- LRCH3 | c.993A>T p.E331D | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.868); catalogued as COSV100605020; called by muse, mutect2, varscan2
- LRFN3 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs775099146, COSV99873241; called by muse, varscan2
- LRFN4 | c.1571del p.G524Vfs*100 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as COSV100540885; called by mutect2, varscan2
- LRP1 | c.11122G>A p.V3708I | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.931); catalogued as rs771787312, COSV99675018; called by muse, mutect2, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 38/109 reads (35%) | catalogued as rs35928649; called by mutect2, pindel, varscan2
- LRP4 | c.5504del p.G1835Afs*9 | Frame Shift Del (DEL) | VAF 33/98 reads (34%) | catalogued as rs745628337; called by mutect2, pindel, varscan2
- LRRC15 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.226); catalogued as rs757264988, COSV61650262; called by muse, mutect2
- LRRC24 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.92); catalogued as COSV99467215; called by muse, mutect2, varscan2
- LRSAM1 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs777784051, COSV100031284; called by muse, mutect2, varscan2
- LTN1 | c.2100del p.V701Sfs*5 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs753955477; called by mutect2, pindel, varscan2
- LUZP1 | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as rs1454162875, COSV56501172; called by muse, mutect2, varscan2
- LY75 | c.3053C>T p.A1018V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.049); catalogued as COSV99716161; called by muse, mutect2
- LZTS2 | c.303del p.S102Afs*41 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs1460451498; called by mutect2, pindel, varscan2
- MAGEB10 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as COSV100775202; called by muse, mutect2, varscan2
- MAGEE1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.739); catalogued as COSV100819330; called by muse, mutect2
- MAGI3 | c.3812G>T p.R1271M | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.224); catalogued as COSV100288410; called by muse, mutect2, varscan2
- MAMDC4 | c.2219G>A p.R740H (on ENST00000445819; = p.R661H on NM_206920.3) | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as rs368530422; called by muse, mutect2, varscan2
- MAN2C1 | c.1707-2A>G p.X569_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99145281; called by muse, mutect2, varscan2
- MAOA | c.1169T>C p.V390A | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV100108672; called by muse, mutect2
- MAP3K1 | c.4073del p.S1358Cfs*19 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | catalogued as COSV101267095; called by mutect2, pindel, varscan2
- MAP3K21 | c.1578G>T p.Q526H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100786083; called by muse, mutect2, varscan2
- MAP4K5 | c.793del p.R265Dfs*8 | Frame Shift Del (DEL) | VAF 24/51 reads (47%) | catalogued as rs746424357; called by mutect2, varscan2
- MATN2 | c.2548G>A p.G850R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.4); catalogued as COSV99645915; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as rs746267361; called by mutect2, varscan2
- MED1 | c.2969G>A p.S990N | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV100327592; called by muse, mutect2, varscan2
- MED12 | c.5464C>T p.H1822Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.932); catalogued as COSV100376752, COSV61335340; called by muse, mutect2, varscan2
- MEGF11 | c.1037A>C p.E346A | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.65); catalogued as COSV99987164; called by muse, mutect2, varscan2
- MEGF8 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs769196067, COSV52079924; called by muse, mutect2
- MEIS2 | c.755G>A p.G252E (on ENST00000561208 / NM_170675.5; = p.G239E on NM_002399.3) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV99576006; called by muse, mutect2, varscan2
- METTL21C | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs140948695; called by muse, mutect2, varscan2
- MFSD1 | c.219T>C p.D73= | Splice Region (SNP) | VAF 7/123 reads (6%) | catalogued as COSV99963679; called by muse, mutect2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MLF2 | c.584A>T p.E195V | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99180065; called by muse, mutect2, varscan2
- MLH3 | c.2393T>C p.L798S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV99469818; called by muse, mutect2, varscan2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs751465048; called by mutect2, varscan2
- MMP24 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs773325169, COSV55768979; called by muse, mutect2, varscan2
- MMS19 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV100512727; called by muse, mutect2, varscan2
- MORN5 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs375743117, COSV65648379; called by muse, mutect2, varscan2
- MRPL34 | c.277T>C p.*93Rext*60 | Nonstop Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99395451; called by muse, mutect2
- MSH5 | c.2465T>C p.M822T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV65173966; called by muse, mutect2, varscan2
- MSI1 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99981421; called by muse, mutect2
- MTARC2 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs761979205, COSV63765667; called by muse, mutect2, varscan2
- MUC5B | c.7860del p.S2621Pfs*27 | Frame Shift Del (DEL) | VAF 44/157 reads (28%) | catalogued as COSV101500795; called by mutect2, pindel, varscan2
- MUC5B | c.14116del p.T4706Pfs*4 | Frame Shift Del (DEL) | VAF 63/178 reads (35%) | catalogued as COSV71592533; called by mutect2, pindel, varscan2
- MXRA5 | c.6238C>T p.R2080C | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369845818, COSV99476140; called by muse, mutect2, varscan2
- MYH1 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs138934137; called by muse, mutect2, varscan2
- MYL5 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV100448392; called by muse, mutect2, varscan2
- MYO10 | c.5812C>T p.Q1938* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | catalogued as COSV99944917; called by muse, mutect2, varscan2
- MYO6 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs760672339, COSV64117739; called by muse, mutect2
- MYOG | c.131C>A p.P44H | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV54096312, COSV99613860; called by muse, mutect2, varscan2
- MYRF | c.2232del p.K745Rfs*45 (on ENST00000278836 / NM_001127392.3; = p.K736Rfs*45 on NM_013279.4) | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | catalogued as COSV99606396; called by mutect2, pindel, varscan2
- NAA25 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.153); catalogued as COSV55702329; called by muse, mutect2, varscan2
- NABP1 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs768187242, COSV100323013; called by muse, mutect2, varscan2
- NCAM1 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 55/144 reads (38%) | catalogued as rs539504433, COSV57515015; called by muse, mutect2, varscan2
- NCAPH2 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs200728457, COSV55372906; called by muse, mutect2, varscan2
- NCK2 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV51888656; called by muse, mutect2, varscan2
- NCOR1 | c.1633A>G p.K545E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.432); catalogued as COSV99248350; called by muse, mutect2, varscan2
- NEB | c.6994G>A p.V2332M | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.166); catalogued as COSV99417417; called by muse, mutect2, varscan2
- NEK4 | c.1856G>T p.R619M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99237341; called by muse, mutect2, varscan2
- NEU2 | c.757C>T p.L253F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.493); catalogued as COSV99290494; called by muse, mutect2, varscan2
- NEUROD4 | c.133A>G p.S45G | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99669813; called by muse, mutect2
- NFIB | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752423267, COSV101100261; called by muse, mutect2, varscan2
- NHLRC1 | c.1090T>C p.S364P | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as COSV100513419; called by mutect2, varscan2
- NIPAL2 | c.945-1G>T p.X315_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100358310; called by muse, mutect2, varscan2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NLGN3 | c.233del p.P78Rfs*67 | Frame Shift Del (DEL) | VAF 10/118 reads (8%) | catalogued as COSV62444223; called by mutect2, pindel
- NLGN3 | c.2270C>T p.A757V (on ENST00000358741 / NM_181303.2; = p.A737V on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.039); catalogued as COSV100704608; called by muse, mutect2
- NLRP11 | c.2710G>A p.A904T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); catalogued as COSV100789668; called by muse, mutect2, varscan2
- NME8 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780172047, COSV99552969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOL6 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99954551; called by muse, mutect2, varscan2
- NOTCH1 | c.5752G>A p.A1918T | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV53034274; called by muse, mutect2, varscan2
- NOTCH3 | c.6065G>A p.R2022H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs778080758, COSV54634025; called by muse, mutect2, varscan2
- NOX1 | c.455del p.G152Vfs*4 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | catalogued as COSV54193992; called by mutect2, pindel, varscan2
- NOXRED1 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100032939; called by muse, mutect2, varscan2
- NUP210 | c.2915T>C p.V972A | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99595784; called by muse, mutect2, varscan2
- NUP58 | c.509C>A p.S170Y | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101098636; called by muse, mutect2, varscan2
- OBSL1 | c.1495C>A p.L499M | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.824); catalogued as COSV54715484, COSV99216431; called by muse, mutect2, varscan2
- OLFML1 | c.313C>A p.L105I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100252527; called by muse, mutect2, varscan2
- OR10G9 | c.776T>C p.L259P | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100901508, COSV66686592; called by muse, mutect2, varscan2
- OR2T33 | c.677T>C p.M226T | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs1388527105, COSV100531722; called by muse, mutect2, varscan2
- OR5B12 | c.401T>C p.M134T | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.842); catalogued as COSV100222364; called by muse, mutect2, varscan2
- ORMDL3 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.214); catalogued as rs1324360197, COSV100401485; called by muse, mutect2
- OSBPL1A | c.2378del p.N793Mfs*15 (on ENST00000319481 / NM_080597.4; = p.N280Mfs*15 on NM_018030.4) | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs751106039; called by mutect2, varscan2
- OTUD6A | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100610942; called by muse, mutect2, varscan2
- PALLD | c.1306A>G p.T436A | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99824178; called by muse, mutect2, varscan2
- PANK4 | c.667T>G p.W223G | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101022328; called by muse, mutect2, varscan2
- PAPSS1 | c.99T>G p.H33Q | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV99491866; called by muse, varscan2
- PARP11 | c.227C>A p.S76Y | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV57396259; called by muse, mutect2, varscan2
- PBX2 | c.1113G>T p.Q371H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100903981; called by muse, mutect2
- PCDH12 | c.1951C>A p.P651T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV99186436; called by muse, mutect2, varscan2
- PCDHGA7 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.025); catalogued as rs1012277194, COSV54004726; called by muse, mutect2, varscan2
- PCDHGA9 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99533238; called by muse, mutect2
- PCED1A | c.922C>A p.L308M | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.34); catalogued as COSV100642831; called by muse, mutect2, varscan2
- PDCD11 | c.4079G>A p.S1360N | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV63934638; called by muse, mutect2, varscan2
- PDCL | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99414087, COSV99414171; called by muse, mutect2, varscan2
- PFKP | c.1785dup p.L596Afs*6 | Frame Shift Ins (INS) | VAF 31/78 reads (40%) | catalogued as rs747416036; called by mutect2, varscan2
- PHF19 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1477901491, COSV100384293; called by muse, mutect2, varscan2
- PHRF1 | c.2281C>A p.P761T (on ENST00000264555 / NM_001286581.2; = p.P760T on NM_020901.4) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs767179863, COSV99199692; called by muse, mutect2, varscan2
- PHTF2 | c.1709del p.L570Cfs*4 (on ENST00000248550 / NM_001366089.1; = p.L532Cfs*4 on NM_020432.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 29/57 reads (51%) | catalogued as rs775426168; called by mutect2, varscan2
- PI4KA | c.6049A>G p.M2017V | Missense Mutation (SNP) | VAF 77/289 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs1169875484, COSV55414632; called by muse, mutect2, varscan2
- PIAS1 | c.1419A>C p.E473D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99986618; called by muse, mutect2, varscan2
- PIAS4 | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.338); catalogued as COSV99518684; called by muse, mutect2
- PIGK | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | catalogued as COSV100769812; called by muse, mutect2, varscan2
- PIK3CA | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs780572147, COSV55904132; called by muse, mutect2, varscan2
- PITPNM3 | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs757552567, COSV52592736; called by muse, mutect2, varscan2
- PKD1 | c.3458C>T p.S1153L | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as rs771225128, COSV99237473; called by muse, mutect2, varscan2
- PKD1L2 | n.1370G>A | Splice Region (SNP) | VAF 5/46 reads (11%) | catalogued as rs970411562; called by muse, mutect2
- PKD2L2 | c.116del p.L39* | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | catalogued as rs1406261366; called by mutect2, pindel, varscan2
- PKHD1L1 | c.6563del p.G2188Efs*28 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | catalogued as rs772426616; called by mutect2, pindel, varscan2
- PKP4 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1320428711, COSV101080472; called by muse, mutect2, varscan2
- PLAU | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as rs149869183; called by muse, mutect2, varscan2
- PLCE1 | c.3796G>A p.D1266N | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV53353161, COSV53372635; called by muse, mutect2, varscan2
- PLEKHA7 | c.3010C>T p.L1004F | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1319736899, COSV100261849; called by muse, mutect2
- PLEKHG4 | c.3196G>A p.V1066I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs775293863, COSV100430742; called by muse, mutect2, varscan2
- PLEKHG7 | c.1470del p.K490Nfs*9 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as COSV60822177; called by mutect2, pindel, varscan2
- PLEKHH3 | c.2104C>T p.H702Y | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as rs1264069110, COSV99257377; called by muse, varscan2
- PLPP7 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV100952557; called by muse, mutect2, varscan2
- PLSCR4 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as rs369071527; called by muse, mutect2, varscan2
- PLXNA1 | c.5680C>A p.L1894M | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.472); catalogued as COSV99302590; called by muse, mutect2
- PLXNB3 | c.5475-1G>T p.X1825_splice | Splice Site (SNP) | VAF 5/52 reads (10%) | catalogued as COSV100737218; called by muse, mutect2, varscan2
- PODXL | c.857G>A p.S286N (on ENST00000378555 / NM_001018111.3; = p.S254N on NM_005397.4) | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100539285; called by muse, mutect2, varscan2
- POLK | c.2171G>A p.S724N | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV99605682; called by muse, mutect2, varscan2
- POLR2F | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 25/45 reads (56%) | catalogued as rs1263678647, COSV101328943; called by muse, mutect2, varscan2
- POMT1 | c.1339-1G>T p.X447_splice | Splice Site (SNP) | VAF 18/40 reads (45%) | catalogued as COSV100586195, COSV61226709; called by muse, mutect2, varscan2
- POTEE | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 18/130 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV100387319; called by mutect2, varscan2
- POU6F2 | c.785A>G p.Q262R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV101302557; called by muse, mutect2, varscan2
- PPIL2 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.662); catalogued as rs561147309, COSV58605424; called by muse, mutect2, varscan2
- PPL | c.1362del p.T455Qfs*37 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | catalogued as rs753902804; called by mutect2, pindel, varscan2
- PPM1A | c.30G>T p.M10I | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100348848, COSV57788747; called by mutect2, varscan2
- PPP1R3A | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs764688600, COSV99492278; called by muse, mutect2
- PPP2R5E | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as COSV100518430; called by muse, mutect2, varscan2
- PPP3CB | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.513); catalogued as rs746120729, COSV55019420; called by muse, mutect2, varscan2
- PPP4R3B | c.1799T>C p.L600P (on ENST00000616407 / NM_001122964.3; = p.L515P on NM_020463.4) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99701598; called by muse, mutect2, varscan2
- PRDM16 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs749076034, COSV54595426, COSV54605228; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRDM16 | c.2204A>G p.H735R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV99575912; called by muse, mutect2, varscan2
- PRDM8 | c.649C>G p.Q217E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as rs924492913, COSV100325014; called by muse, varscan2
- PRICKLE2 | c.1052G>A p.R351Q (on ENST00000295902; = p.R295Q on NM_198859.4) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); catalogued as rs545235523, COSV99896811, COSV99897007; called by muse, mutect2, varscan2
- PRKACA | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254121699, COSV100431910; called by muse, mutect2, varscan2
- PRKCSH | c.1440C>T p.T480= | Splice Region (SNP) | VAF 31/88 reads (35%) | catalogued as rs371330547; called by muse, mutect2, varscan2
- PRPF4B | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs867970797, COSV61784045; called by muse, mutect2, varscan2
- PRPF8 | c.6469G>A p.V2157M | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs750741891, COSV100025383; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs781858060; called by mutect2, varscan2
- PSEN2 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs139972151; ClinVar: likely benign; called by muse, mutect2, varscan2
- PSKH1 | c.848T>C p.L283P | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52123727, COSV99344542; called by muse, mutect2, varscan2
- PSME4 | c.1640T>C p.V547A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV66368888; called by muse, mutect2, varscan2
- PSMG1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.883); catalogued as rs372682958; called by muse, mutect2, varscan2
- PTBP3 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV100534098; called by muse, mutect2, varscan2
- PTK7 | c.2204T>C p.L735P | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV100029975; called by muse, mutect2, varscan2
- PTPN14 | c.3314G>A p.S1105N | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV65283211; called by muse, mutect2
- PTPN14 | c.1369C>A p.L457M | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100872413, COSV65285687; called by muse, mutect2, varscan2
- PTPN3 | c.1934C>T p.T645M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1361970381, COSV52705303; called by muse, mutect2, varscan2
- PTPRF | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs771269220, COSV100740725; called by muse, mutect2, varscan2
- PTPRM | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751624252; called by muse, mutect2, varscan2
- PTPRT | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776642212, COSV61959822; called by muse, mutect2, varscan2
- PTPRT | c.2772C>T p.Y924= | Splice Region (SNP) | VAF 18/35 reads (51%) | catalogued as rs758202722, COSV100626023; called by muse, mutect2, varscan2
- PTPRT | c.2387G>T p.R796M | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV61977775; called by muse, mutect2, varscan2
- PUS7L | c.87C>A p.S29R | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as COSV100786491; called by muse, mutect2, varscan2
- PYHIN1 | c.1202del p.N401Ifs*94 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as rs1294788483; called by mutect2, pindel, varscan2
- QKI | c.401del p.K134Rfs*14 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs755727862; called by mutect2, varscan2
- QPCT | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100621541; called by muse, mutect2, varscan2
- RAB33B | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59777422; called by muse, mutect2, varscan2
- RAB40AL | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as rs761581070, COSV99505037; called by muse, mutect2, varscan2
- RAD54L | c.1885_1887del p.E629del | In Frame Del (DEL) | VAF 19/69 reads (28%) | catalogued as rs746553748; called by pindel, varscan2
- RALYL | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759722399, COSV101569085; called by muse, mutect2, varscan2
- RANBP2 | c.9641G>A p.R3214Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs370647782; called by muse, mutect2, varscan2
- RASA1 | c.2478G>T p.Q826H | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99169668; called by muse, mutect2, varscan2
- RDH13 | c.247C>T p.R83C (on ENST00000415061 / NM_001145971.2; = p.R12C on NM_138412.4) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs183720506; called by muse, mutect2, varscan2
- RELB | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV99672793; called by muse, mutect2, varscan2
- RFK | c.202A>G p.N68D | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100946884; called by muse, mutect2
- RFX2 | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100353608; called by muse, mutect2, varscan2
- RGS12 | c.2545A>G p.S849G | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.851); catalogued as COSV100122691; called by muse, mutect2, varscan2
- RHOG | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV53464891, COSV99544135; called by muse, mutect2, varscan2
- RNASEL | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100842559; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF185 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV99839665; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 30/55 reads (55%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNH1 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV100596695; called by muse, mutect2, varscan2
- RPGRIP1 | c.2684C>A p.P895H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99250649; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV100271528; called by muse, mutect2, varscan2
- RPL28 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.046); catalogued as rs772932918, COSV100689382; called by muse, mutect2, varscan2
- RPTOR | c.3562G>A p.G1188S | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100155524; called by muse, mutect2
- RRH | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100496013; called by muse, mutect2, varscan2
- RRM2B | c.4G>T p.G2C | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); catalogued as COSV52566687; called by muse, mutect2, varscan2
- RYR2 | c.4556C>T p.T1519I | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100768871; called by muse, mutect2, varscan2
- SAFB | c.1723A>G p.I575V | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.838); catalogued as COSV52653080; called by muse, mutect2, varscan2
- SAGE1 | c.1748A>G p.H583R | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.155); catalogued as rs782574608, COSV100186864; called by muse, mutect2, varscan2
- SALL4 | c.3142A>G p.N1048D | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as COSV99409307; called by muse, mutect2
- SAPCD2 | c.1082T>C p.I361T | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101294032; called by muse, mutect2, varscan2
- SASH1 | c.2309C>A p.P770H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100821011; called by muse, mutect2, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs765867975; called by mutect2, varscan2
- SCAMP5 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV100723797; called by muse, mutect2, varscan2
- SEC16A | c.6197del p.P2066Qfs*76 | Frame Shift Del (DEL) | VAF 29/82 reads (35%) | catalogued as COSV99256980; called by mutect2, pindel, varscan2
- SELENBP1 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100923616, COSV64373565; called by muse, mutect2, varscan2
- SEMA6A | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as COSV99962930; called by muse, mutect2, varscan2
- SERPINE3 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201739179; called by muse, mutect2, varscan2
- SETD7 | c.1026del p.K344Rfs*14 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | catalogued as rs35259575; called by mutect2, pindel, varscan2
- SETX | c.7058C>T p.T2353M | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs201629099, COSV99809120; called by muse, mutect2, varscan2
- SGPP1 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.695); catalogued as COSV99905747; called by muse, mutect2
- SH2D4B | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV57893258; called by muse, mutect2, varscan2
- SHE | c.959G>T p.R320M | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100495898; called by muse, mutect2, varscan2
- SHISA5 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99604438; called by muse, mutect2, varscan2
- SLC12A4 | c.1126C>T p.L376F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100311431; called by muse, mutect2, varscan2
- SLC12A6 | c.1568C>T p.A523V (on ENST00000354181 / NM_001365088.1; = p.A472V on NM_005135.2) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99271269; called by muse, mutect2, varscan2
- SLC26A8 | c.2913G>T p.*971Yext*4 | Nonstop Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100839399; called by muse, mutect2, varscan2
- SLC27A5 | c.1879del p.H627Ifs*17 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | catalogued as rs777720763; called by mutect2, pindel, varscan2
- SLC35G5 | c.773C>T p.A258V | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs1201390191, COSV99644071; called by muse, mutect2, varscan2
- SLC6A1 | c.1162A>G p.M388V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV55113858; called by muse, mutect2, varscan2
- SLC6A11 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99594215; called by muse, mutect2
- SLIT2 | c.1836G>A p.M612I | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV99881999; called by muse, mutect2, varscan2
- SMARCA4 | c.4559G>A p.R1520H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.359); catalogued as COSV60794292; called by muse, mutect2, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs747405143; called by mutect2, pindel, varscan2
- SMYD5 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50265106; called by muse, mutect2, varscan2
- SOS2 | c.3814C>T p.R1272C | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1005498417, COSV53567762, COSV53575599; called by muse, mutect2, varscan2
- SOX5 | c.1692G>A p.M564I | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100506305, COSV58644723; called by muse, mutect2, varscan2
- SPEG | c.5420T>C p.M1807T | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs957102380, COSV100403702; called by muse, mutect2, varscan2
- SPEG | c.6942del p.R2315Gfs*38 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | catalogued as rs1452292712; called by mutect2, pindel
- SPOUT1 | c.102del p.K34Nfs*7 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs749421754; ClinVar: uncertain significance; called by mutect2, varscan2
- SPP2 | c.70T>C p.Y24H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99394464; called by muse, mutect2, varscan2
- SPRTN | c.533C>T p.P178L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233235170, COSV99149548; called by muse, mutect2, varscan2
- STAG3 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as rs774733921, COSV100425739; called by muse, mutect2, varscan2
- STIL | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV99680727; called by muse, mutect2, varscan2
- STK33 | c.1081C>A p.L361I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); catalogued as COSV100173793; called by muse, mutect2, varscan2
- SUPT5H | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs570927495, COSV63241257; called by muse, mutect2, varscan2
- SURF6 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100790762; called by muse, mutect2, varscan2
- SUSD5 | c.1711A>G p.S571G | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100534994; called by muse, mutect2
- SYN2 | c.1507G>A p.G503S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.036); catalogued as rs765147797; called by muse, mutect2, varscan2
- SYNE2 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766378548, COSV59968960; called by muse, mutect2, varscan2
- TAAR1 | c.944T>C p.L315P | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs758707759, COSV51588690; called by muse, mutect2, varscan2
- TAB3 | c.89A>G p.Q30R | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV99915959; called by muse, mutect2, varscan2
- TAF1 | c.1241C>T p.A414V (on ENST00000373790 / NM_138923.4; = p.A435V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99334980; called by muse, mutect2, varscan2
- TAF1 | c.1877del p.K626Rfs*4 (on ENST00000373790 / NM_138923.4; = p.K647Rfs*4 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs745516519; called by mutect2, varscan2
- TAF5L | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99272838; called by muse, mutect2, varscan2
- TARBP2 | c.775C>T p.R259W (on ENST00000266987 / NM_134323.2; = p.R238W on NM_004178.4) | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs746965828, COSV57199253; called by muse, mutect2, varscan2
- TAS1R2 | c.2032C>A p.P678T | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV100946163; called by muse, mutect2, varscan2
- TBC1D19 | c.1181A>G p.Y394C | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99336089; called by muse, mutect2
- TBC1D22A | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV100452749, COSV61446716; called by muse, mutect2, varscan2
- TBX6 | c.621+1G>A p.X207_splice | Splice Site (SNP) | VAF 59/127 reads (46%) | catalogued as COSV99661549; called by muse, mutect2, varscan2
- TCF20 | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV100166377; called by muse, mutect2, varscan2
- TCF25 | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV99642529; called by muse, mutect2, varscan2
- TCTN1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100885921; called by muse, mutect2, varscan2
- TCTN3 | c.536A>G p.N179S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.334); catalogued as rs943000517, COSV99796668; called by muse, mutect2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs763321097; called by mutect2, varscan2
- TENM2 | c.3181G>A p.E1061K (on ENST00000518659 / NM_001122679.2; = p.E829K on NM_001080428.3) | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs1464106409, COSV69133110; called by muse, mutect2, varscan2
- TFCP2 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs915173272, COSV99227526; called by muse, mutect2, varscan2
- THAP10 | c.99G>T p.W33C | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV99537110; called by muse, mutect2, varscan2
- THSD7B | c.752G>A p.C251Y | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55720579; called by muse, mutect2, varscan2
- THSD7B | c.1524del p.G509Dfs*58 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | catalogued as rs1236522898, COSV55712401; called by mutect2, pindel, varscan2
- TM4SF1 | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 46/101 reads (46%) | catalogued as rs34567733; called by muse, mutect2, varscan2
- TMEM132A | c.1417del p.V473Cfs*16 (on ENST00000453848 / NM_178031.3; = p.V474Cfs*16 on NM_017870.4) | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs773292133; called by mutect2, pindel, varscan2
- TMEM45B | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.531); catalogued as rs765825131, COSV99859269; called by muse, mutect2, varscan2
- TMEM51 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV101051497; called by muse, mutect2, varscan2
- TMPRSS5 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100244527; called by muse, varscan2
- TNKS1BP1 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100835875; called by muse, mutect2, varscan2
- TNRC6A | c.323A>C p.Q108P | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs974004477, COSV100169623; called by muse, mutect2, varscan2
- TNS3 | c.621G>A p.M207I | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV100235113; called by muse, mutect2, varscan2
- TOGARAM2 | c.2110A>G p.M704V | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.69); catalogued as COSV101090948; called by muse, mutect2, varscan2
- TOP1MT | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100239287; called by muse, mutect2, varscan2
- TP53 | c.1146del p.K382Nfs*40 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | catalogued as CD126191; called by mutect2, pindel, varscan2
- TPST2 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs914288696, COSV100113997; called by muse, mutect2
- TRAPPC8 | c.2030T>G p.V677G | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51967159, COSV99350740; called by muse, mutect2
- TRERF1 | c.2524G>T p.G842W | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61675273; called by muse, mutect2, varscan2
- TRIM43 | c.510C>T p.G170= | Splice Region (SNP) | VAF 51/123 reads (41%) | catalogued as COSV99719892; called by muse, mutect2, varscan2
- TRIO | c.2227A>G p.I743V | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.072); catalogued as COSV100710061; called by muse, mutect2, varscan2
- TRIOBP | c.3731C>A p.P1244H | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV100730735; called by muse, mutect2, varscan2
- TRO | c.3301G>A p.G1101S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.313); catalogued as rs773140897, COSV99436029; called by muse, mutect2, varscan2
- TRPM2 | c.529del p.A177Pfs*6 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | catalogued as rs762935066, COSV55967995; called by mutect2, pindel, varscan2
- TRPM8 | c.2202del p.F735Sfs*49 | Frame Shift Del (DEL) | VAF 36/148 reads (24%) | catalogued as COSV61222098; called by mutect2, pindel, varscan2
- TRRAP | c.7718C>T p.T2573M (on ENST00000359863 / NM_001244580.1; = p.T2555M on NM_003496.3) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs76587346, COSV62839015; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs756650873; called by mutect2, varscan2
- TTN | c.100598G>A p.R33533H (on ENST00000591111; = p.R26109H on NM_003319.4) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | PolyPhen benign (0.018); catalogued as rs756575734, COSV60234961; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.83302C>T p.R27768C (on ENST00000591111; = p.R20344C on NM_003319.4) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | PolyPhen probably damaging (0.998); catalogued as rs756724511, COSV59952095; called by muse, mutect2, varscan2
- TTN | c.73349C>A p.P24450Q (on ENST00000591111; = p.P17026Q on NM_003319.4) | Missense Mutation (SNP) | VAF 11/113 reads (10%) | PolyPhen probably damaging (0.999); catalogued as COSV100600595; called by muse, mutect2
- TTN | c.56041A>C p.K18681Q (on ENST00000591111; = p.K11257Q on NM_003319.4) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | PolyPhen probably damaging (0.923); catalogued as COSV100600598; called by muse, mutect2, varscan2
- TTN | c.33541_33543del p.E11181del (on ENST00000591111; = p.E10254del on NM_133378.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 15/62 reads (24%) | catalogued as rs763098227; called by pindel, varscan2
- TTN | c.28645C>T p.H9549Y (on ENST00000591111; = p.H8622Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | PolyPhen possibly damaging (0.67); catalogued as COSV100600607; called by muse, mutect2, varscan2
- TYRO3 | c.2182C>T p.R728C | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148896634; called by muse, mutect2, varscan2
- UBE3A | c.1929dup p.K644Efs*7 | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | catalogued as COSV51661184; called by mutect2, pindel, varscan2
- UBQLNL | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100974081; called by muse, mutect2, varscan2
- UBR4 | c.15209C>T p.A5070V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100920578; called by muse, mutect2, varscan2
- UBTF | c.386A>G p.K129R | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100255831; called by muse, mutect2, varscan2
- ULK1 | c.872C>G p.P291R | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV100416618; called by muse, mutect2, varscan2
- UNC13B | c.526+3_526+6del p.X176_splice | Splice Site (DEL) | VAF 32/106 reads (30%) | catalogued as rs758138869; called by mutect2, pindel, varscan2
- UPF1 | c.2620C>A p.L874M (on ENST00000599848 / NM_001297549.2; = p.L863M on NM_002911.4) | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV99439030; called by muse, mutect2, varscan2
- UQCRB | c.60G>C p.W20C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99749051; called by muse, mutect2, varscan2
- USP11 | c.2747A>G p.Q916R (on ENST00000218348; = p.Q873R on NM_001371072.1) | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.385); catalogued as COSV99510784; called by muse, mutect2, varscan2
- USP26 | c.1044dup p.K349* | Frame Shift Ins (INS) | VAF 24/70 reads (34%) | catalogued as rs772870708; called by mutect2, varscan2
- USP28 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.234); catalogued as COSV50178858, COSV99134701; called by muse, mutect2, varscan2
- USP40 | c.3192G>A p.L1064= | Splice Region (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99296035; called by muse, mutect2, varscan2
- VARS2 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV99461611; called by muse, mutect2, varscan2
- VARS2 | c.2206G>C p.V736L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100422752; called by muse, mutect2, varscan2
- VAV1 | c.272G>A p.S91N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100408740; called by muse, mutect2, varscan2
- WARS2 | c.901C>A p.R301S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV99346104; called by muse, mutect2, varscan2
- WDFY3 | c.6040A>G p.M2014V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV55693883; called by muse, mutect2, varscan2
- WDR24 | c.323G>A p.R108H (on ENST00000248142; = p.R46H on NM_032259.4) | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50208857; called by muse, mutect2, varscan2
- WDR6 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs981114396, COSV100556118; called by muse, mutect2
- WDR62 | c.2342C>T p.T781M | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs372603166; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 24/38 reads (63%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WNT5B | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1417763285, COSV100148606; called by muse, mutect2, varscan2
- WRAP73 | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV99573195; called by muse, mutect2, varscan2
- XCR1 | c.933G>T p.Q311H | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as COSV100499318; called by muse, mutect2, varscan2
- XPNPEP3 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs752721668, COSV100846596, COSV100846835; called by muse, mutect2, varscan2
- YY1AP1 | c.1883C>T p.A628V (on ENST00000295566 / NM_139118.2; = p.A571V on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.916); catalogued as rs936331319, COSV99803651; called by muse, mutect2, varscan2
- YY2 | c.669del p.L224Yfs*18 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as COSV63412713; called by mutect2, pindel, varscan2
- Z83844.2 | c.987del p.E330Rfs*9 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs1569008643; called by mutect2, pindel, varscan2
- ZBTB40 | c.2597G>A p.C866Y | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100988847; called by muse, mutect2, varscan2
- ZC3H14 | c.1774C>T p.Q592* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV99192985; called by muse, mutect2, varscan2
- ZDBF2 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV100984483, COSV65630474; called by muse, mutect2, varscan2
- ZDHHC4 | c.161A>G p.H54R | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs1562540452, COSV100253863; called by muse, mutect2, varscan2
- ZFX | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100457437; called by muse, mutect2, varscan2
- ZHX2 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV100072725; called by muse, mutect2, varscan2
- ZMYND8 | c.1904del p.K635Sfs*14 (on ENST00000311275 / NM_001363741.2; = p.K655Sfs*14 on NM_012408.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs776813452; called by mutect2, varscan2
- ZNF100 | c.1509_1510del p.H503Qfs*17 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | catalogued as rs780630140; called by mutect2, pindel, varscan2
- ZNF213 | c.82T>A p.W28R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101205950; called by muse, mutect2, varscan2
- ZNF248 | c.1253G>A p.C418Y | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.804); catalogued as COSV100627507; called by muse, mutect2, varscan2
- ZNF30 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV100340401; called by muse, mutect2, varscan2
- ZNF438 | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100061488; called by muse, mutect2, varscan2
- ZNF516 | c.2821G>A p.A941T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765789208, COSV101487227; called by muse, mutect2, varscan2
- ZNF598 | c.1214C>T p.T405I | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV101461936; called by muse, mutect2, varscan2
- ZNF611 | c.1739A>G p.Y580C | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.796); catalogued as COSV100160133; called by muse, mutect2, varscan2
- ZNF648 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs757839353, COSV100374479; called by muse, varscan2
- ZNF654 | c.3067G>A p.V1023I | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as COSV100525644; called by muse, mutect2, varscan2
- ZNF701 | c.894del p.K298Nfs*4 (on ENST00000301093; = p.K232Nfs*4 on NM_018260.3) | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | catalogued as rs762217868; called by mutect2, pindel, varscan2
- ZNF808 | c.2318G>A p.R773H | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as rs267605638, COSV63119640; called by muse, mutect2, varscan2
- ZNFX1 | c.5696C>T p.A1899V | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as COSV100872241; called by muse, mutect2, varscan2
- ZSCAN20 | c.2699A>T p.E900V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100792515; called by muse, mutect2, varscan2
- ZZEF1 | c.6799G>A p.A2267T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs200209672, COSV101067625; called by muse, mutect2, varscan2
- AARS2 | c.2284del p.D762Tfs*31 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- ABCA1 | c.3763_3764del p.S1255Wfs*5 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by pindel, varscan2
- ABCC1 | c.2386_2387del p.A797Sfs*11 | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | called by pindel, varscan2
- AKR1B10 | c.730del p.T244Pfs*6 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | called by mutect2, pindel, varscan2
- AMBRA1 | c.2463del p.H822Mfs*22 (on ENST00000458649 / NM_001367468.1; = p.H732Mfs*22 on NM_017749.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 22/51 reads (43%) | called by mutect2, pindel, varscan2
- AMH | c.208del p.L70Cfs*7 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- AMMECR1 | c.220del p.Q74Rfs*89 | Frame Shift Del (DEL) | VAF 21/46 reads (46%) | called by pindel, varscan2
- ANKRD12 | c.1956del p.K652Nfs*4 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | called by mutect2, varscan2
- APEH | c.271del p.E91Nfs*3 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- AQP1 | c.508del p.A171Pfs*6 | Frame Shift Del (DEL) | VAF 19/85 reads (22%) | called by mutect2, pindel, varscan2
- ARHGEF40 | c.3332del p.P1111Lfs*5 | Frame Shift Del (DEL) | VAF 27/65 reads (42%) | called by mutect2, pindel, varscan2
- ATP10B | c.2223dup p.T742Dfs*3 | Frame Shift Ins (INS) | VAF 4/41 reads (10%) | called by mutect2, pindel
- BCL2L2 | c.570dup p.A191Cfs*2 | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- BPIFB4 | c.240del p.K80Nfs*153 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by pindel, varscan2
- BRD1 | c.1474del p.L492Cfs*24 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- BRPF3 | c.2561dup p.E855Gfs*9 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | called by mutect2, varscan2
- C17orf50 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2
- C19orf47 | c.471del p.R158Gfs*138 | Frame Shift Del (DEL) | VAF 35/104 reads (34%) | called by mutect2, pindel, varscan2
- C3orf14 | c.176dup p.D60Gfs*20 | Frame Shift Ins (INS) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- CASS4 | c.245dup p.F83Ifs*32 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- CENPE | c.6157del p.M2053Wfs*7 | Frame Shift Del (DEL) | VAF 45/147 reads (31%) | called by mutect2, pindel, varscan2
- CEP290 | c.5649del p.K1883Nfs*2 | Frame Shift Del (DEL) | VAF 10/89 reads (11%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- CHRDL1 | c.922del p.I308* (on ENST00000372045; = p.I314* on NM_145234.4) | Frame Shift Del (DEL) | VAF 43/132 reads (33%) | called by mutect2, pindel, varscan2
- CLCC1 | c.1218del p.T407Lfs*17 (on ENST00000356970 / NM_001377464.1; = p.T357Lfs*17 on NM_015127.5) | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | called by mutect2, pindel, varscan2
- CRBN | c.633del p.K211Nfs*27 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by pindel, varscan2
- CROT | c.1792del p.C598Vfs*6 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- CWF19L2 | c.1398del p.E467Nfs*22 | Frame Shift Del (DEL) | VAF 14/108 reads (13%) | called by mutect2, pindel, varscan2
- DAAM2 | c.1574del p.P525Lfs*11 | Frame Shift Del (DEL) | VAF 23/70 reads (33%) | called by mutect2, pindel, varscan2
- DACT1 | c.1363del p.T455Rfs*52 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | called by mutect2, pindel, varscan2
- DDX17 | c.488del p.G163Efs*20 | Frame Shift Del (DEL) | VAF 25/83 reads (30%) | called by mutect2, pindel, varscan2
- DDX39B | c.447del p.F149Lfs*13 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, varscan2
- DNAH5 | c.13458del p.F4486Lfs*7 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- EAF2 | c.631A>G p.N211D | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.015); called by muse, mutect2
- EAPP | c.374del p.K125Rfs*55 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | called by mutect2, varscan2
- ECPAS | c.3612del p.F1204Lfs*17 | Frame Shift Del (DEL) | VAF 27/86 reads (31%) | called by mutect2, pindel, varscan2
- EEF1G | c.911_912del p.S304Cfs*11 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | called by pindel, varscan2
- EFCAB7 | c.543del p.K181Nfs*2 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, pindel, varscan2
- EFNB3 | c.991del p.Q331Rfs*39 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- EMILIN3 | c.717_718del p.R239Sfs*41 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by pindel, varscan2
- EP300 | c.6970del p.H2324Tfs*29 | Frame Shift Del (DEL) | VAF 23/59 reads (39%) | called by mutect2, pindel, varscan2
- ERBIN | c.2356del p.T786Hfs*11 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- FAM214A | c.469del p.S157Lfs*3 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- FAT1 | c.10790del p.G3597Afs*3 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- FIGN | c.1587del p.T530Qfs*26 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | called by mutect2, pindel, varscan2
- FUBP1 | c.902del p.I301Nfs*22 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- GSDMD | c.1275del p.L427Sfs*21 | Frame Shift Del (DEL) | VAF 36/112 reads (32%) | called by mutect2, pindel, varscan2
- IGLV1-44 | c.102del p.Q35Rfs*19 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | called by mutect2, pindel, varscan2
- INTS12 | c.191dup p.N64Kfs*5 | Frame Shift Ins (INS) | VAF 37/124 reads (30%) | called by mutect2, pindel, varscan2
- IRGC | c.427dup p.R143Pfs*13 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- ITGB4 | c.1692_1693dup p.E565Vfs*205 | Frame Shift Ins (INS) | VAF 22/65 reads (34%) | called by mutect2, varscan2
- ITSN1 | c.299del p.P100Lfs*3 | Frame Shift Del (DEL) | VAF 11/86 reads (13%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, varscan2
- KDM3A | c.2716del p.I906Sfs*25 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- KIAA1522 | c.1322del p.P441Lfs*13 (on ENST00000373480 / NM_001198972.2; = p.P500Lfs*13 on NM_020888.3) | Frame Shift Del (DEL) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- KIAA1614 | c.2615del p.P872Hfs*129 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- KIDINS220 | c.4417del p.L1473Wfs*35 | Frame Shift Del (DEL) | VAF 29/76 reads (38%) | called by mutect2, pindel, varscan2
- LCT | c.3831del p.L1278* | Frame Shift Del (DEL) | VAF 37/141 reads (26%) | called by mutect2, pindel, varscan2
- LRP3 | c.2255del p.P752Rfs*26 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- LRRK2 | c.1605del p.K535Nfs*13 | Frame Shift Del (DEL) | VAF 13/80 reads (16%) | called by mutect2, pindel, varscan2
- MAN2C1 | c.406del p.E136Kfs*13 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- MAP10 | c.220del p.T74Rfs*48 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- MAVS | c.360del p.T121Hfs*70 | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | called by mutect2, pindel, varscan2
- MIDEAS | c.411_412del p.H137Qfs*23 | Frame Shift Del (DEL) | VAF 45/174 reads (26%) | called by pindel, varscan2
- MST1 | c.901_904del p.K301Vfs*224 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel, varscan2
- MTAP | c.571del p.A191Rfs*6 | Frame Shift Del (DEL) | VAF 23/61 reads (38%) | called by mutect2, pindel, varscan2
- MTG1 | c.986del p.P329Rfs*28 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | called by mutect2, pindel, varscan2
- MYBL1 | c.1259del p.N420Tfs*13 | Frame Shift Del (DEL) | VAF 52/122 reads (43%) | called by mutect2, varscan2
- MYH9 | c.3682del p.E1228Sfs*6 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- NSD3 | c.598del p.S200Afs*20 | Frame Shift Del (DEL) | VAF 64/193 reads (33%) | called by mutect2, pindel, varscan2
- OR56A4 | c.488del p.L163* | Frame Shift Del (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel, varscan2
- PDCD6IP | c.81_82del p.Q27Hfs*46 | Frame Shift Del (DEL) | VAF 31/96 reads (32%) | called by mutect2, pindel, varscan2
- PEX1 | c.1208dup p.N403Kfs*15 | Frame Shift Ins (INS) | VAF 41/82 reads (50%) | called by mutect2, varscan2
- PHRF1 | c.3718del p.L1240Cfs*47 (on ENST00000264555 / NM_001286581.2; = p.L1239Cfs*47 on NM_020901.4) | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- PIK3R3 | c.883del p.M295* | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- PIP4K2B | c.427T>C p.Y143H | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.049); called by muse, mutect2
- PPP2R3B | c.1165del p.T389Hfs*70 | Frame Shift Del (DEL) | VAF 50/130 reads (38%) | called by mutect2, varscan2
- PROP1 | c.529del p.S177Pfs*59 | Frame Shift Del (DEL) | VAF 9/96 reads (9%) | called by mutect2, pindel, varscan2
- PROX1 | c.126del p.F42Lfs*4 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | called by pindel, varscan2
- PRRT2 | c.347_348del p.K116Rfs*17 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by mutect2, pindel, varscan2
- PTEN | c.188dup p.N63Kfs*11 | Frame Shift Ins (INS) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- PTEN | c.867del p.V290* | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- PTPMT1 | c.565del p.R189Gfs*27 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- RAI1 | c.1340dup p.N447Kfs*31 | Frame Shift Ins (INS) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- RASIP1 | c.2666del p.P889Lfs*37 | Frame Shift Del (DEL) | VAF 28/78 reads (36%) | called by mutect2, pindel, varscan2
- RBL1 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- RPS9 | c.144del p.F48Lfs*14 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- SAV1 | c.420del p.F140Lfs*49 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, varscan2
- SBNO2 | c.1918del p.R640Gfs*75 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- SCAF11 | c.3850_3851insA p.P1284Hfs*23 | Frame Shift Ins (INS) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- SH3GL1 | c.1057_1058dup p.F354Afs*121 | Frame Shift Ins (INS) | VAF 10/91 reads (11%) | called by mutect2, pindel, varscan2
- SH3RF1 | c.1183_1184del p.L395Efs*41 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- SHOC1 | c.4333dup p.*1445Lfs*21 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | called by mutect2, varscan2
- SI | c.1-3del | Splice Region (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- SLC52A3 | c.882del p.C295Afs*88 | Frame Shift Del (DEL) | VAF 26/73 reads (36%) | called by mutect2, pindel, varscan2
246 further variants in this file (19 protein-altering or splice-affecting, 209 silent, 18 other) are not listed here.
